Surgical pathology report (de-identified scan), TCGA case TCGA-FA-8693, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Asterand, specimen TCGA-FA-8693-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]		
[REDACTED] Case ID	[REDACTED] ID	Excision date
[REDACTED]	[REDACTED]	[REDACTED]

[page 2 of 3]
Gross Description	Microscopic Description	Diagnosis Details
Part of the stomach with saucer-like tumor up to 5.5 cm in size, with muscle layer invasion. In the fatty tissue there are soft hyperemic lymph nodes. Omentum is hyperemic.	The 1st conclusion: in the gastric wall there is a tumor with diffuse type of growth, which is consisted of small-size cells with hyperchromatic nuclei. Tumor is replace gastric mucosa and spread on the muscle layer. Morphological structure is consistent with non-Hodgkin's lymphoma. IHC-stainings are recommended. Fifteen lymph nodes demonstrated reactive changes. Omentum demonstrated focal lymphoid infiltration. The 2nd conclusion: in the gastric wall there is a tumor, which is consist of middle-sized lymphoid cells, but there are some regions with large atypical cells with high proliferative activity. IHC stainings: CD20+, CD3-, CD5-, CD10-, CyclinD1-, Ki67 - focaly 60%. Final conclusion: Non-Hodgkin's marginal zone B-cell lymphoma	Tumor Features: Unknown, Tumor Extent: 0, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 3 of 3]
Comments	Formatted Path Report
IHC stainings: CD20+, CD3-, CD5-, CD10-, CyclinD1-, Ki67 - focaly 60%.	STOMACH TISSUE CHECKLIST Specimen type: Subtotal resection of stomach Tumor site: Antrum Tumor size: 0 x 0 x 5.5 cm Tumor features: None specified Histologic type: Diffuse large b-cell lymphoma Histologic grade: Tumor extent: Not specified Lymph nodes: 0/15 positive for metastasis (Greater and lesser curvature. 0/15) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file 8dd481c3-6570-49b6-aa3c-861d6d8c6503 (TCGA-FA-8693.977683B9-1CAD-4033-9825-7DBB84B171E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).